Somatic mutation profile of tumor specimen TCGA-VQ-A8PO-01A (aliquot TCGA-VQ-A8PO-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PO, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.6 years (27,250 days).
Specimen TCGA-VQ-A8PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d95ce0e4-cddf-44fd-b00e-8eb66dc3c9fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PO-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PO-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9931e86-12cb-41dc-a009-40e25f9e8ef4

The open-access MAF lists 1,009 somatic variants for this specimen: 771 protein-altering or splice-affecting, 220 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 496, Silent 220, Frame Shift Del 199, Frame Shift Ins 41, Splice Site 14, Nonsense Mutation 11, 3'UTR 8, Intron 7, In Frame Del 7, 5'UTR 1, 3'Flank 1, Nonstop Mutation 1.

Variants (750 of 1,009; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.96dup p.L33Tfs*9 | Frame Shift Ins (INS) | VAF 43/168 reads (26%) | catalogued as rs747322175; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- ALOX12B | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199545653, CM071548, COSV59874271; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALPL | c.662del p.G221Vfs*56 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs769948289; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1016del p.K339Rfs*2 | Frame Shift Del (DEL) | VAF 56/211 reads (27%) | catalogued as rs80357569, CD951606; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.15640C>T p.R5214C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123728, CM114916, COSV56407525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 9/76 reads (12%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by pindel, varscan2
- AACS | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.398); catalogued as rs769170664, COSV99907769; called by muse, mutect2, varscan2
- ABCA7 | c.3665A>G p.Q1222R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99565216; called by muse, mutect2, varscan2
- ABCB4 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM147042, COSV99709795; called by muse, mutect2
- ABCC10 | c.1412T>C p.V471A (on ENST00000372530 / NM_001198934.2; = p.V428A on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV99766751; called by muse, mutect2, varscan2
- ABCC5 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1236684724, COSV99656439; called by muse, mutect2, varscan2
- ABCC6 | c.4208G>T p.S1403I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52743982, COSV99228110; called by muse, mutect2, varscan2
- AC136428.1 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs745896044, COSV101434941; called by muse, mutect2, varscan2
- ACTR8 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV51638455; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 44/88 reads (50%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS10 | c.1726A>C p.S576R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99546494; called by muse, mutect2, varscan2
- ADAMTS2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs144554943, COSV52381631; called by muse, mutect2, varscan2
- ADAMTS20 | c.4541A>G p.D1514G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1375341910, COSV101238957; called by muse, mutect2, varscan2
- ADAMTS5 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99537069; called by muse, mutect2, varscan2
- ADCK5 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100450221; called by muse, mutect2, varscan2
- ADCY10 | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.714); catalogued as COSV100896588; called by muse, mutect2, varscan2
- ADCY3 | c.1243del p.V415Cfs*27 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as COSV53172762; called by mutect2, pindel, varscan2
- ADCY8 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV53903997; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRL3 | c.1036A>G p.T346A (on ENST00000506720 / NM_001322402.2; = p.T278A on NM_015236.6) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101546871; called by muse, mutect2, varscan2
- AGAP1 | c.1774C>T p.Q592* (on ENST00000304032 / NM_001037131.3; = p.Q539* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV58337172; called by muse, mutect2, varscan2
- AGAP6 | c.1511A>C p.E504A (on ENST00000374056 / NM_001365867.1; = p.E527A on NM_001077665.2) | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100929043, COSV100929072; called by muse, mutect2
- AGRN | c.1877C>G p.P626R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); catalogued as COSV101038598; called by muse, varscan2
- AHCTF1 | c.3208C>T p.P1070S (on ENST00000366508; = p.P1044S on NM_015446.5) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100403150; called by muse, mutect2, varscan2
- AHCTF1 | c.986+1G>C p.X329_splice (on ENST00000366508; = p.X303_splice on NM_015446.5) | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100403151; called by muse, mutect2, varscan2
- AHNAK2 | c.7475C>T p.S2492L | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1238349733, COSV60918759; called by muse, mutect2, varscan2
- AKAP12 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV99482469; called by muse, varscan2
- ALDOC | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV99256632; called by muse, mutect2, varscan2
- AMZ2 | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1555739250, COSV100703104; called by muse, mutect2
- ANK1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs764420355, COSV99224091; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANK3 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99778456; called by muse, mutect2
- ANKAR | c.2297T>C p.L766S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853901; called by muse, mutect2, varscan2
- ANKDD1A | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100132590; called by muse, mutect2, varscan2
- ANKH | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99414595; called by muse, mutect2, varscan2
- ANKRD52 | c.1922G>A p.G641D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99921056; called by muse, mutect2
- AP1M1 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99358193; called by muse, mutect2
- AP4M1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100384647; called by muse, mutect2, varscan2
- APOF | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100028619; called by muse, mutect2, varscan2
- AQP2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV99550741; called by muse, mutect2, varscan2
- ARAP2 | c.4057G>A p.A1353T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs1362804192, COSV100394155; called by muse, mutect2, varscan2
- ARFGEF2 | c.5327A>C p.Q1776P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100904003; called by muse, mutect2, varscan2
- ARHGEF17 | c.2393A>G p.E798G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99734938; called by muse, mutect2, varscan2
- ARHGEF19 | c.1581+2T>C p.X527_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99580069; called by muse, mutect2
- ARMH4 | c.1265C>A p.T422K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.28); catalogued as COSV50778151, COSV99957690; called by muse, mutect2, varscan2
- ASAP3 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100369217; called by muse, mutect2, varscan2
- ASH1L | c.4735T>C p.C1579R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100853137; called by muse, mutect2, varscan2
- ASH1L | c.971del p.K324Sfs*8 | Frame Shift Del (DEL) | VAF 36/169 reads (21%) | catalogued as COSV64214768; called by mutect2, pindel, varscan2
- ATG4A | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100619573; called by muse, mutect2, varscan2
- ATG9B | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100939881; called by muse, mutect2, varscan2
- ATP1A4 | c.1220A>G p.E407G | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV100927446; called by muse, mutect2, varscan2
- ATP2A1 | c.2714T>C p.V905A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100706837; called by muse, mutect2, varscan2
- ATP4A | c.2420T>C p.V807A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99382160; called by muse, mutect2, varscan2
- ATP7B | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs757281957, COSV99666080; called by muse, mutect2, varscan2
- ATXN2L | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100293670, COSV57368871; called by muse, mutect2, varscan2
- B3GNT6 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs374685479; called by muse, mutect2
- B4GALNT2 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375362269; called by muse, mutect2
- BAG1 | c.222_224del p.K75del | In Frame Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs764755467; called by pindel, varscan2
- BAHCC1 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV100311192; called by muse, mutect2
- BAHCC1 | c.5920T>C p.Y1974H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100311193; called by muse, mutect2
- BAP1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56236367; called by muse, mutect2
- BARHL2 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV100966027; called by muse, mutect2, varscan2
- BCAS1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101006027; called by muse, mutect2, varscan2
- BCL9L | c.1196T>C p.L399S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99418632; called by muse, varscan2
- BPTF | c.4219T>C p.C1407R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100074147; called by muse, mutect2, varscan2
- BRD8 | c.2551T>C p.S851P (on ENST00000254900 / NM_139199.2; = p.S924P on NM_006696.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99136611; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV99607370; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C1orf116 | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100847880; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C4orf51 | c.187A>C p.S63R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as COSV101439977; called by muse, mutect2, varscan2
- C5orf38 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100121588; called by muse, mutect2, varscan2
- C6orf118 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57819241; called by muse, mutect2, varscan2
- CACNA1B | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749131489, COSV99495386; called by muse, mutect2, varscan2
- CACNA2D3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs1553898213, COSV55549370; called by muse, mutect2, varscan2
- CACTIN | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698302; called by muse, mutect2
- CADM3 | c.760T>G p.C254G (on ENST00000368125 / NM_001127173.3; = p.C288G on NM_021189.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100930262; called by muse, mutect2, varscan2
- CADPS2 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100460837; called by muse, mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs770273913; called by mutect2, varscan2
- CASP8AP2 | c.1015A>C p.S339R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV99386779; called by muse, mutect2, varscan2
- CASR | c.2060C>T p.T687M (on ENST00000490131; = p.T764M on NM_000388.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs145209598; called by mutect2, varscan2
- CASZ1 | c.1666-1G>A p.X556_splice | Splice Site (SNP) | VAF 43/117 reads (37%) | catalogued as COSV59742552; called by muse, mutect2, varscan2
- CAVIN1 | c.706T>C p.F236L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100824503; called by muse, mutect2, varscan2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs368765497; called by mutect2, pindel, varscan2
- CCDC116 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99489138; called by muse, mutect2, varscan2
- CCDC130 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99237225; called by muse, mutect2
- CCDC189 | c.669T>A p.D223E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100079369; called by muse, mutect2, varscan2
- CCDC88A | c.3008del p.N1003Ifs*40 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs763821011, COSV55065347; called by mutect2, varscan2
- CCND1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99919240; called by muse, mutect2, varscan2
- CCNH | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761675040, COSV99907148; called by muse, mutect2
- CCR7 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1365219236, COSV55850218; called by muse, mutect2, varscan2
- CCT5 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs201810364, COSV54723915; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs762194001; called by mutect2, varscan2
- CDCA2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs201480361, COSV57944067; called by muse, mutect2, varscan2
- CDH1 | c.521del p.N174Tfs*41 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV55737132; called by mutect2, varscan2
- CDH1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); catalogued as COSV55732942, COSV99931292; called by muse, mutect2, varscan2
- CDH5 | c.1271del p.K424Rfs*20 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as COSV58520449; called by mutect2, pindel, varscan2
- CDH6 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54073002; called by muse, mutect2, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | catalogued as rs1561075636; called by mutect2, pindel, varscan2
- CDH7 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100541482; called by muse, mutect2, varscan2
- CEACAM20 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100386794; called by muse, mutect2, varscan2
- CEP152 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs776732911, COSV57858352; called by muse, mutect2, varscan2
- CEP250 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1207807940; called by muse, mutect2, varscan2
- CEP290 | c.2657T>A p.I886N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100467900; called by mutect2, varscan2
- CEP85L | c.663dup p.R222Tfs*10 | Frame Shift Ins (INS) | VAF 15/91 reads (16%) | catalogued as rs1464311844; called by mutect2, pindel, varscan2
- CES2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs752262052, COSV100399070; called by muse, mutect2, varscan2
- CHMP2A | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV99447955; called by muse, mutect2, varscan2
- CHST10 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as COSV99958703; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLEC16A | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as rs201162849, COSV68498982; called by muse, mutect2, varscan2
- CLIP2 | c.42del p.K15Sfs*73 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | catalogued as COSV56275983; called by mutect2, pindel, varscan2
- CLPX | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs769111203, COSV99037905; called by muse, mutect2, varscan2
- CNDP1 | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62595919; called by muse, mutect2, varscan2
- CNGA3 | c.1966A>G p.M656V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99736132; called by muse, mutect2, varscan2
- CNGB1 | c.2183T>G p.M728R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99201530; called by muse, mutect2, varscan2
- CNIH2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100268326; called by muse, mutect2, varscan2
- COL12A1 | c.9091A>T p.N3031Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100485445; called by muse, mutect2, varscan2
- COL28A1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101258326; called by muse, mutect2, varscan2
- COL4A3 | c.4313C>A p.P1438H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV101169966; called by muse, mutect2
- COL4A4 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs371326070, COSV61629224, COSV61632536; called by muse, mutect2, varscan2
- COL6A3 | c.5701T>C p.F1901L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99796315; called by muse, mutect2, varscan2
- COL7A1 | c.5441G>A p.R1814H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756258247, COSV60392875, COSV60397289; called by muse, mutect2
- CORO2B | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99962914; called by muse, mutect2, varscan2
- CPB2 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs944258391, COSV99472958; called by muse, mutect2, varscan2
- CPD | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as rs771349056, COSV56711929; called by muse, mutect2, varscan2
- CRY1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99150385; called by muse, mutect2, varscan2
- CSE1L | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs773313816, COSV99521842; called by muse, mutect2
- CSK | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99583449; called by muse, mutect2, varscan2
- CSMD3 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52327866, COSV99825639; called by muse, mutect2, varscan2
- CSNK2A2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52641297, COSV52642546; called by muse, mutect2, varscan2
- CSTF1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV99410100; called by muse, mutect2, varscan2
- CTNND1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1375089467, COSV100649820; called by muse, mutect2, varscan2
- CYP26C1 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99591489; called by muse, mutect2, varscan2
- CYP2A13 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770474654, COSV100386645; called by muse, mutect2, varscan2
- DALRD3 | c.758A>C p.E253A (on ENST00000341949 / NM_001009996.3; = p.E86A on NM_018114.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100482747; called by muse, mutect2, varscan2
- DCAF4 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100610919; called by muse, mutect2, varscan2
- DCAF8L1 | c.1790G>T p.C597F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV101491393; called by muse, mutect2, varscan2
- DCLK1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55175130; called by muse, mutect2, varscan2
- DCSTAMP | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1242656583, COSV99886102; called by muse, mutect2, varscan2
- DDOST | c.229A>G p.K77E (on ENST00000415136; = p.K60E on NM_005216.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99928566; called by muse, mutect2, varscan2
- DDX10 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100489075; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX58 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs1254591679, COSV101152508; called by muse, mutect2
- DEPDC5 | c.2644A>G p.T882A (on ENST00000400246; = p.T951A on NM_014662.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.033); catalogued as COSV99834448; called by muse, mutect2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs756920263; called by mutect2, varscan2
- DHTKD1 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145427732; called by muse, mutect2, varscan2
- DHX34 | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749202413, COSV60895893; called by muse, mutect2, varscan2
- DIS3 | c.2032del p.I678Ffs*59 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs771690280; called by mutect2, varscan2
- DIS3L2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs762653147, COSV56063436; called by muse, mutect2, varscan2
- DLL4 | c.1965A>G p.I655M | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV99989604; called by muse, mutect2, varscan2
- DMD | c.9418C>A p.Q3140K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100626051, COSV58963058; called by muse, mutect2, varscan2
- DMXL2 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.296); catalogued as COSV99195983; called by muse, mutect2, varscan2
- DNAH3 | c.11068C>A p.L3690I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV99765116; called by muse, mutect2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs34468832; called by mutect2, varscan2
- DNMT3L | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV99533171; called by muse, mutect2, varscan2
- DOCK1 | c.4171G>T p.G1391C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99726937; called by muse, mutect2, varscan2
- DPP10 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100059220, COSV59691338; called by muse, mutect2, varscan2
- DPP10 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100059224, COSV59672496; called by muse, mutect2, varscan2
- DPYSL4 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100633840; called by muse, mutect2, varscan2
- DRD3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99879187; called by muse, mutect2, varscan2
- DSEL | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59491747; called by muse, mutect2, varscan2
- DSTYK | c.2411T>C p.M804T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100904474; called by muse, mutect2, varscan2
- DUOX2 | c.2879T>C p.I960T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV101199573; called by muse, mutect2, varscan2
- DYNAP | c.62A>G p.D21G (on ENST00000321600; = p.D24G on NM_001307955.1) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs773416779, COSV58666290; called by muse, mutect2, varscan2
- DYSF | c.3134T>C p.L1045P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.934); catalogued as COSV99244537; called by muse, mutect2, varscan2
- EBNA1BP2 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99355826; called by muse, mutect2, varscan2
- EHD3 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100434628; called by mutect2, varscan2
- EHF | c.114del p.F38Lfs*51 | Frame Shift Del (DEL) | VAF 22/133 reads (17%) | catalogued as rs1356113739, COSV99140965; called by mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs748937918; called by mutect2, varscan2
- ELAPOR2 | c.2867T>C p.L956P (on ENST00000450689 / NM_001142749.3; = p.L789P on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788235; called by muse, mutect2, varscan2
- ELOA2 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99795977; called by muse, mutect2
- ENPEP | c.2736dup p.A913Cfs*13 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs768719919; called by mutect2, pindel, varscan2
- EPCAM | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99764027; called by muse, mutect2, varscan2
- ERCC3 | c.777A>T p.E259D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs772883177, COSV53425973; called by muse, mutect2, varscan2
- ERN2 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55623453; called by muse, mutect2, varscan2
- ERN2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV56833098; called by muse, mutect2, varscan2
- ESR2 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99962849; called by muse, mutect2
- ETFA | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99144174; called by muse, mutect2, varscan2
- EXTL3 | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99593763; called by muse, mutect2, varscan2
- EXTL3 | c.2557T>G p.S853A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99593764, COSV99593829; called by muse, mutect2, varscan2
- FAM111B | c.1933T>C p.F645L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100639236; called by muse, mutect2, varscan2
- FAM13C | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53257921, COSV99513125; called by muse, mutect2, varscan2
- FAM166C | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100297090; called by muse, mutect2, varscan2
- FAM171A1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs962236898, COSV100968062, COSV65314371; called by muse, mutect2, varscan2
- FAM90A1 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV100274199; called by muse, mutect2
- FBH1 | c.706C>A p.L236M (on ENST00000362091 / NM_178150.3; = p.L287M on NM_032807.4) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100758617, COSV62984441; called by muse, mutect2, varscan2
- FBXO39 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs202030641, COSV100386080; called by muse, mutect2, varscan2
- FCGBP | c.11831C>T p.T3944M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs184463001; called by muse, mutect2, varscan2
- FGFR4 | c.2278A>G p.T760A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99448887; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | catalogued as rs749851531; called by mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs1216734611; called by mutect2, pindel, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs774060142; called by mutect2, varscan2
- FLII | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV100493481; called by muse, mutect2, varscan2
- FNIP2 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV100032206; called by muse, mutect2, varscan2
- FOXJ2 | c.917A>C p.Q306P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs745407957, COSV99368130; called by muse, mutect2, varscan2
- FOXP1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs540360773, COSV59517465; called by muse, mutect2, varscan2
- FOXP2 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.184); catalogued as COSV100646261; called by muse, varscan2
- FPGT-TNNI3K | c.845del p.F282Sfs*15 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs751624085; called by mutect2, pindel, varscan2
- FRAS1 | c.6674C>T p.A2225V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99348487; called by muse, mutect2, varscan2
- FRY | c.6352C>A p.L2118M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100968821; called by muse, mutect2, varscan2
- FUT8 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100651067; called by muse, mutect2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | catalogued as rs751048223; called by mutect2, varscan2
- FZD6 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100708305; called by muse, mutect2, varscan2
- FZR1 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553409; called by muse, mutect2, varscan2
- GBX1 | c.777del p.S261Afs*26 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | catalogued as COSV52547067; called by mutect2, pindel, varscan2
- GC | c.726del p.V243Cfs*12 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | catalogued as rs1290895118; called by mutect2, pindel, varscan2
- GFM2 | c.1603A>G p.M535V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs532678363, COSV99714064; called by muse, mutect2, varscan2
- GGN | c.809del p.G270Afs*20 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV53057105; called by mutect2, pindel, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | catalogued as rs750227570; called by mutect2, varscan2
- GMPR2 | c.260A>G p.E87G (on ENST00000355299 / NM_001351022.2; = p.E105G on NM_016576.5) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV99164594; called by muse, mutect2
- GNAS | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1555891595, COSV55677462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | catalogued as rs763679060; called by mutect2, varscan2
- GP1BA | c.624del p.F208Lfs*48 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs868628165; called by mutect2, pindel, varscan2
- GP5 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV100540667; called by muse, mutect2
- GPATCH4 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs762613137, COSV58039134; called by muse, mutect2, varscan2
- GPR135 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751362794, COSV101229292; called by muse, mutect2, varscan2
- GPR139 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100429640, COSV58505527; called by muse, mutect2
- GPR146 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV52465583; called by muse, mutect2
- GPR45 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256576888, COSV99306700; called by muse, mutect2, varscan2
- GPRC5D | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs370153735; called by muse, mutect2, varscan2
- GRIK2 | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as COSV100023354; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs760757380; called by mutect2, varscan2
- GSDMC | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99415605; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- H2AX | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99597817; called by muse, mutect2, varscan2
- H2AZ2 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99760425; called by muse, mutect2, varscan2
- HABP2 | c.1384del p.R462Afs*10 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV63488832, COSV63490651; called by mutect2, pindel, varscan2
- HAPLN4 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99363637; called by muse, mutect2, varscan2
- HBZ | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs137878147; called by muse, mutect2, varscan2
- HDAC7 | c.1130G>A p.R377H (on ENST00000427332; = p.R416H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757098292, COSV50387308; called by muse, mutect2, varscan2
- HELLS | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99491747; called by muse, mutect2, varscan2
- HGF | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55946352, COSV55949356; called by muse, mutect2, varscan2
- HINT3 | c.547T>C p.*183Rext*72 | Nonstop Mutation (SNP) | VAF 27/131 reads (21%) | catalogued as COSV57650378; called by muse, mutect2, varscan2
- HKDC1 | c.2093del p.G698Vfs*20 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs771959819; called by mutect2, pindel, varscan2
- HLA-DPA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs770307009, COSV70089438; called by muse, mutect2, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs1557991740, COSV65568693; called by mutect2, pindel, varscan2
- HNF4A | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100291085; called by muse, mutect2, varscan2
- HNRNPH3 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99769604; called by muse, mutect2, varscan2
- HOXB4 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV60178862; called by muse, mutect2
- HOXB5 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs1423604013, COSV99494375; called by muse, mutect2, varscan2
- HPS4 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV100404060; called by muse, mutect2, varscan2
- HPS5 | c.2718G>A p.R906= (on ENST00000349215 / NM_181507.2; = p.R792= on NM_007216.4) | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100752236; called by muse, mutect2, varscan2
- HSP90B1 | c.743+2T>C p.X248_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100236326; called by muse, mutect2, varscan2
- HSPA8 | c.1921A>T p.T641S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99914218; called by muse, mutect2, varscan2
- HSPB7 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs764260228, COSV100317809; called by muse, mutect2, varscan2
- IFNG | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1285316047, COSV57491590; called by muse, mutect2, varscan2
- IGHV3-53 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs782011069; called by mutect2, pindel, varscan2
- IL17C | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1055363132, COSV99733134, COSV99733282; called by muse, mutect2
- IL17RD | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56341940, COSV99576609; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs1352150703; called by mutect2, varscan2
- ITGAD | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs751119063, COSV101210335; called by muse, mutect2, varscan2
- ITPKA | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53027256, COSV99540588; called by muse, mutect2, varscan2
- ITPKC | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs142308355; called by muse, mutect2, varscan2
- ITSN1 | c.472del p.L158Wfs*37 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as COSV66083080; called by mutect2, pindel, varscan2
- IVD | c.17C>T p.T6I (on ENST00000651168; = p.T3I on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99991378; called by muse, mutect2, varscan2
- JAG1 | c.2702C>A p.P901H | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV99652459; called by muse, mutect2, varscan2
- JMJD1C | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV101232208; called by muse, mutect2, varscan2
- KANK2 | c.2095C>A p.R699S (on ENST00000586659 / NM_001379562.1; = p.R707S on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100763037, COSV62007383; called by muse, mutect2, varscan2
- KCNA10 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871399; called by muse, mutect2, varscan2
- KCNG1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs577545086, COSV100856988; called by muse, mutect2
- KCNH5 | c.1355T>C p.M452T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV100525451; called by muse, mutect2, varscan2
- KCNJ3 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99715184, COSV99715296; called by muse, mutect2, varscan2
- KCNJ8 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); catalogued as rs750317966, COSV99557389; called by muse, mutect2, varscan2
- KCNK9 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100270402; called by muse, mutect2
- KCTD10 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); catalogued as COSV99949054; called by muse, mutect2, varscan2
- KIF13A | c.1292T>C p.M431T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV99434023; called by muse, mutect2, varscan2
- KIF15 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100392526, COSV99079793; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLHL24 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416650091, COSV99664720; called by muse, mutect2, varscan2
- KLHL31 | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100911734; called by muse, mutect2, varscan2
- KMT2C | c.9794A>G p.Y3265C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100067466; called by muse, mutect2, varscan2
- KMT2C | c.6313G>A p.V2105M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100067472; called by muse, mutect2, varscan2
- KMT2C | c.4390G>A p.V1464I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100067478; called by muse, mutect2
- KMT2C | c.2864T>C p.L955S | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100067483; called by muse, mutect2
- KRT24 | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV99231925; called by muse, mutect2, varscan2
- KRT35 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99877683; called by muse, mutect2, varscan2
- KRTAP5-5 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV101294149; called by muse, mutect2, varscan2
- LBP | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99460426; called by muse, mutect2, varscan2
- LEMD3 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100384194; called by muse, mutect2, varscan2
- LENG8 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs749114468, COSV100457146; called by muse, mutect2, varscan2
- LETM1 | c.432del p.A145Qfs*5 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs745839823; called by mutect2, pindel, varscan2
- LGI3 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV60443220; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs780042765; called by mutect2, varscan2
- LMO7 | c.4393_4394insA p.L1465Hfs*4 (on ENST00000357063; = p.L1146Hfs*4 on NM_005358.5) | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as COSV100412499; called by mutect2, pindel, varscan2
- LMTK2 | c.3062T>C p.L1021P | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV99806080; called by muse, mutect2, varscan2
- LMX1A | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376967723; called by muse, mutect2, varscan2
- LOXL4 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99583606; called by muse, mutect2
- LRBA | c.5186C>G p.A1729G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100840976; called by muse, mutect2, varscan2
- LRCH3 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs374224629; called by muse, mutect2, varscan2
- LRCH4 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100052715; called by muse, mutect2, varscan2
- LRIG3 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs528252114, COSV100292432; called by muse, mutect2, varscan2
- LRRC8A | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs113017554, COSV52183609; called by muse, mutect2, varscan2
- LRRIQ1 | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV101279545; called by muse, mutect2, varscan2
- LRRN1 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100076058; called by muse, mutect2, varscan2
- LRRN4 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101125370; called by muse, mutect2, varscan2
- LTB | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473731879, COSV101438041; called by muse, mutect2, varscan2
- LTBP1 | c.4540G>A p.E1514K (on ENST00000404816 / NM_206943.4; = p.E1188K on NM_000627.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs766040820, COSV104378399, COSV99697673; called by muse, mutect2
- LUM | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs912133731, COSV99898899; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGI1 | c.431-1G>T p.X144_splice | Splice Site (SNP) | VAF 19/44 reads (43%) | catalogued as COSV100439445; called by muse, mutect2, varscan2
- MAP3K12 | c.2372T>C p.M791T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV99912975; called by muse, mutect2, varscan2
- MAP3K4 | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100815062; called by muse, mutect2, varscan2
- MAP4 | c.2897C>T p.T966I | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs771820978, COSV99274747; called by muse, mutect2, varscan2
- MAP9 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.164); catalogued as COSV100250749; called by muse, mutect2, varscan2
- MAU2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.13); catalogued as rs1235656281, COSV99448330; called by muse, mutect2, varscan2
- MCHR1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99967741; called by muse, mutect2, varscan2
- MED24 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.624); catalogued as COSV100672999; called by muse, mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs759225724, COSV53895347; called by mutect2, varscan2
- MERTK | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99774107; called by muse, mutect2, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | catalogued as rs778939334; called by mutect2, pindel, varscan2
- MIDEAS | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.374); catalogued as rs771853802, COSV99678619; called by muse, varscan2
- MLLT10 | c.1231dup p.V411Gfs*3 | Frame Shift Ins (INS) | VAF 24/180 reads (13%) | catalogued as rs747811015; called by mutect2, varscan2
- MMP13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs767829684, COSV52823318; called by muse, mutect2, varscan2
- MMP26 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.635); catalogued as COSV100331975; called by muse, mutect2, varscan2
- MON1B | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1276371446, COSV99941544; called by muse, mutect2
- MPL | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs367877736, COSV100991337, COSV65244494; called by muse, mutect2, varscan2
- MRPS12 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1225449479, COSV55500282; called by muse, mutect2
- MST1R | c.1580G>A p.C527Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99617803; called by muse, mutect2, varscan2
- MTFMT | c.836T>C p.M279T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99584146; called by muse, mutect2, varscan2
- MTMR8 | c.2065G>T p.G689C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100878298; called by muse, mutect2, varscan2
- MUC15 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99846186, COSV99846319; called by muse, mutect2, varscan2
- MUC16 | c.16921T>C p.S5641P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV101198302; called by muse, mutect2, varscan2
- MUC16 | c.12281C>T p.A4094V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV101198304; called by muse, mutect2, varscan2
- MYBPC1 | c.797A>G p.K266R (on ENST00000550270 / NM_206820.2; = p.K291R on NM_002465.4) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV62251312; called by muse, mutect2, varscan2
- MYO15A | c.10051C>T p.R3351C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1015545804, COSV99231286; called by muse, mutect2, varscan2
- MYO1C | c.2078G>T p.G693V (on ENST00000648651 / NM_001080779.2; = p.G658V on NM_033375.5) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100704252; called by muse, mutect2
- MYOD1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100000147, COSV51454056; called by muse, mutect2
- MYOM3 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100292495; called by muse, mutect2, varscan2
- N4BP3 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.628); catalogued as COSV99200603; called by muse, mutect2, varscan2
- NAV1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs146415554, CM137457; called by muse, mutect2, varscan2
- NCAPH | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs1204477489, COSV99545556; called by muse, mutect2, varscan2
- NCOR1 | c.2908T>C p.S970P | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV99247627; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | catalogued as rs747914168; called by mutect2, varscan2
- NEB | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768295694, COSV99415282; called by muse, mutect2, varscan2
- NEBL | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769728098, COSV65802410, COSV65806116; called by muse, mutect2, varscan2
- NEURL4 | c.2780A>T p.E927V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100222703; called by muse, mutect2, varscan2
- NF1 | c.6135G>T p.L2045F (on ENST00000358273 / NM_001042492.3; = p.L2024F on NM_000267.3) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100646078; called by muse, mutect2, varscan2
- NFKBID | c.885G>T p.E295D (on ENST00000396901; = p.E447D on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV100573192; called by muse, mutect2
- NHLRC1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100513393; called by muse, mutect2
- NLGN3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241064136, COSV100704562, COSV62444132; called by muse, mutect2, varscan2
- NLRC5 | c.5548A>G p.R1850G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99346526; called by muse, mutect2
- NLRX1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs950696257, COSV99423734; called by muse, mutect2, varscan2
- NOMO1 | c.3659G>T p.R1220M | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99814229; called by muse, mutect2
- NOP9 | c.771del p.Q258Rfs*3 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV51865167; called by mutect2, pindel, varscan2
- NOSTRIN | c.1452del p.G485Afs*27 (on ENST00000317647 / NM_001039724.4; = p.G407Afs*27 on NM_052946.3) | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as COSV58322092; called by mutect2, pindel, varscan2
- NOVA1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs370779053; called by muse, mutect2, varscan2
- NPAS2 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV100175812; called by muse, mutect2, varscan2
- NPC1L1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV56928895; called by muse, mutect2, varscan2
- NR1D1 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99225288; called by muse, mutect2
- NRXN1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1404175088, COSV68022267; called by muse, mutect2, varscan2
- NTN1 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs376278603; called by muse, mutect2, varscan2
- NUMA1 | c.3856C>T p.R1286C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs775941295, COSV100705825; called by muse, mutect2, varscan2
- NUP160 | c.2775+2T>C p.X925_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV101021315; called by muse, mutect2, varscan2
- NXPH2 | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as COSV99740172; called by muse, mutect2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OBSCN | c.15041T>G p.L5014R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99473255; called by muse, varscan2
- OPHN1 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100830224; called by muse, mutect2, varscan2
- OR10H1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs762967326, COSV100612371; called by muse, mutect2, varscan2
- OR10S1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV101602445; called by muse, mutect2, varscan2
- OR14K1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV99314968; called by muse, mutect2
- OR4C46 | c.90dup p.V31Cfs*38 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | catalogued as rs759167019; called by mutect2, pindel, varscan2
- OR8D4 | c.14del p.N5Tfs*5 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as COSV58431151; called by mutect2, pindel, varscan2
- PAPPA2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs368485332, COSV62776395; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PARP10 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs529405414, COSV100477740; called by muse, mutect2
- PARP9 | c.2561A>G p.D854G | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV64449789; called by muse, mutect2, varscan2
- PARS2 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs975310267, COSV100988282; called by muse, mutect2, varscan2
- PAX7 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as COSV100946598; called by muse, mutect2, varscan2
- PCARE | c.3307A>G p.R1103G | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs375443061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCBP4 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778090769, COSV100436911; called by muse, mutect2, varscan2
- PCDHA11 | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.033); catalogued as COSV100247842; called by muse, mutect2, varscan2
- PCDHA6 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV65342638; called by muse, mutect2, varscan2
- PCDHB15 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs782712005, COSV99178825; called by muse, mutect2, varscan2
- PCNX4 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as rs1283596127, COSV100469934; called by muse, mutect2
- PDCD6IP | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs541852500, COSV100218525; called by mutect2, varscan2
- PDE1C | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100371137; called by muse, mutect2, varscan2
- PDK4 | c.1058T>C p.L353S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV50010219; called by muse, mutect2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZD2 | c.8371G>T p.A2791S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.33); catalogued as COSV99223824; called by muse, mutect2, varscan2
- PDZRN4 | c.2143G>T p.D715Y (on ENST00000402685 / NM_001164595.2; = p.D457Y on NM_013377.4) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100113686, COSV54193857; called by muse, mutect2, varscan2
- PELP1 | c.2029A>G p.M677V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99342534; called by muse, mutect2, varscan2
- PEX26 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100299030; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF10 | c.1448dup p.T484Nfs*18 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs754137375; called by mutect2, varscan2
- PIEZO2 | c.6986A>G p.Y2329C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV99554497; called by muse, mutect2, varscan2
- PIK3C2B | c.2536T>C p.C846R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100915992; called by muse, mutect2, varscan2
- PIK3R2 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs757901079, COSV99717214; called by muse, mutect2, varscan2
- PLA1A | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56334691; called by muse, mutect2, varscan2
- PLCB4 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs759180836, COSV53801605; called by muse, mutect2, varscan2
- PLEKHM3 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV101216285; called by muse, mutect2, varscan2
- PLPP7 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963332839, COSV64840979; called by muse, mutect2, varscan2
- PLXNC1 | c.4244C>A p.P1415H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312497; called by muse, mutect2, varscan2
- PLXND1 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs752323651, COSV60715927; called by muse, varscan2
- PNKP | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1453288814, COSV55589066, COSV99681573; ClinVar: uncertain significance; called by muse, mutect2
- POLQ | c.2708T>G p.L903R | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV99951675; called by muse, mutect2, varscan2
- POLR3A | c.3606G>T p.Q1202H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100965543; called by muse, mutect2, varscan2
- POM121L12 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749109595, COSV101374850; called by muse, mutect2
- PPAN-P2RY11 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1243406012, COSV99460863; called by muse, mutect2, varscan2
- PPFIBP1 | c.2881C>T p.Q961* (on ENST00000318304 / NM_177444.3; = p.Q955* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99944338; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs775130624; called by mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PRAG1 | c.1951A>G p.S651G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100421892; called by muse, mutect2, varscan2
- PRDM15 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1208727629, COSV99519390; called by muse, mutect2, varscan2
- PRICKLE3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100889890; called by muse, mutect2, varscan2
- PRNP | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs779528653, COSV101057190; called by muse, mutect2, varscan2
- PROC | c.1212del p.M406Wfs*15 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | catalogued as CM951029; called by mutect2, pindel
- PROKR2 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.841); catalogued as COSV99449888; called by muse, mutect2, varscan2
- PROS1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101260283, COSV67776463; called by muse, mutect2, varscan2
- PRPF8 | c.4805A>G p.D1602G | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as COSV100517161; called by muse, mutect2, varscan2
- PRSS55 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs753600571, COSV100153636; called by muse, mutect2, varscan2
- PRX | c.2189C>A p.P730H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99397488; called by muse, mutect2
- PSEN2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100422847; called by muse, mutect2, varscan2
- PSG4 | c.64+2T>C p.X22_splice | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99736338; called by muse, mutect2, varscan2
- PSME4 | c.3392G>A p.R1131H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.35); catalogued as rs753202778, COSV66363271; called by muse, mutect2, varscan2
- PTCRA | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780570974, COSV100485707; called by muse, mutect2, varscan2
- PTDSS1 | c.728G>T p.R243M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100428482; called by muse, mutect2, varscan2
- PTGS1 | c.381del p.T128Pfs*17 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs779702921; called by mutect2, pindel, varscan2
- PTPN21 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.031); catalogued as rs1239536771, COSV100161529; called by muse, varscan2
- PTPN21 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs772450718, COSV60851805; called by muse, varscan2
- PTPRT | c.3203A>C p.Q1068P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100625453; called by muse, mutect2, varscan2
- PWP1 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69833874; called by muse, mutect2, varscan2
- PYHIN1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs767179319, COSV100932325; called by muse, mutect2, varscan2
- RAD51AP2 | c.1859del p.N620Ifs*2 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs754599664, COSV104433747; called by mutect2, pindel, varscan2
- RALY | c.842A>G p.E281G (on ENST00000246194 / NM_016732.3; = p.E265G on NM_007367.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV99865537; called by muse, mutect2
- RAPGEF4 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51417596; called by muse, mutect2
- RAPGEF6 | c.4311T>A p.S1437R | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99725388; called by muse, mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs771909008; called by mutect2, varscan2
- RBBP8 | c.2406dup p.E803Rfs*12 | Frame Shift Ins (INS) | VAF 9/72 reads (13%) | catalogued as rs1173769568; called by mutect2, pindel, varscan2
- RBM23 | c.905G>A p.R302H (on ENST00000359890 / NM_001077351.2; = p.R286H on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs557116761, COSV100321307; called by muse, mutect2, varscan2
- RBM34 | c.353del p.K118Sfs*9 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | catalogued as rs747042720; called by mutect2, pindel, varscan2
- RBM45 | c.746G>A p.R249H (on ENST00000616198 / NM_001365579.1; = p.R247H on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.7); catalogued as rs546729723, COSV99617515; called by muse, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as rs749563266; called by mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | catalogued as rs761285857; called by mutect2, varscan2
- RBPJ | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.857); catalogued as COSV100623518; called by muse, mutect2, varscan2
- RFX1 | c.912C>A p.S304R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.763); catalogued as COSV54334134, COSV99585807; called by muse, mutect2, varscan2
- RHEX | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100520017; called by muse, mutect2, varscan2
- RIMS1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746162365, COSV53442940; called by muse, mutect2, varscan2
- RNF20 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV101206503; called by muse, mutect2, varscan2
- ROS1 | c.6767A>G p.D2256G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100876533, COSV63862624; called by muse, mutect2, varscan2
- RPAIN | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100506752; called by muse, mutect2, varscan2
- RPP38 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs907467683, COSV100975466; called by muse, mutect2, varscan2
- RPS6KA4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as rs1360811119, COSV99589812; called by muse, mutect2, varscan2
- RTCB | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV99321931; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs747510098; called by mutect2, varscan2
- RXRG | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100717239; called by muse, mutect2, varscan2
- RYR1 | c.8606G>T p.R2869L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100614601; called by muse, mutect2, varscan2
- SAT1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100803848; called by muse, mutect2, varscan2
- SDC1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99587076; called by muse, mutect2, varscan2
- SDS | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99785202; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SELENOF | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100085841; called by muse, mutect2, varscan2
- SEMA5B | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466335803, COSV52104147; called by muse, mutect2, varscan2
- SEPTIN14 | c.898del p.T300Pfs*53 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs768200923, COSV66432100; called by mutect2, pindel, varscan2
- SEPTIN8 | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV99736036; called by muse, mutect2, varscan2
- SEZ6 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.444); catalogued as COSV100252698; called by muse, mutect2, varscan2
- SF3B2 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as rs771761232, COSV59428958; called by muse, mutect2, varscan2
- SFRP1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55173142; called by muse, mutect2
- SGCG | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs375766013; ClinVar: uncertain significance; called by muse, varscan2
- SGSH | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs541847913, CD972444, COSV58339580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3BGRL | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV100943253; called by muse, mutect2, varscan2
- SH3TC1 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV99794451; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHE | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100495859; called by muse, mutect2, varscan2
- SHOC1 | c.1539del p.K513Nfs*9 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs1321256439; called by mutect2, pindel, varscan2
- SHROOM1 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100166957; called by muse, mutect2, varscan2
- SIGLEC7 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771229132, COSV99978326; called by muse, mutect2, varscan2
- SIRPB2 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63123817; called by muse, mutect2, varscan2
- SIX2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV57391966; called by muse, mutect2
- SKAP1 | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV100411375; called by muse, mutect2, varscan2
- SLC12A1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182552195; called by muse, mutect2, varscan2
- SLC12A4 | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs747407048, COSV99862855; called by muse, mutect2, varscan2
- SLC1A1 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746465299, COSV99261180; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC25A22 | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100204107; called by muse, mutect2, varscan2
- SLC2A3 | c.568T>C p.F190L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99306286; called by muse, mutect2, varscan2
- SLC30A2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100958485; called by muse, mutect2, varscan2
- SLC30A4 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV99970128; called by muse, mutect2, varscan2
- SLC32A1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs778982202, COSV54147935; called by muse, mutect2, varscan2
- SLC33A1 | c.1279A>G p.S427G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV100848249; called by muse, mutect2
- SLC3A1 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.063); catalogued as COSV99576847; called by muse, mutect2, varscan2
- SLC5A7 | c.1258del p.Q420Sfs*26 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | catalogued as rs1558872453, COSV50890615; called by mutect2, pindel, varscan2
- SLC6A4 | c.1317+2T>C p.X439_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99911224; called by muse, mutect2, varscan2
- SLC9A1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs527454172, COSV99849305; called by muse, mutect2, varscan2
- SLITRK5 | c.2716del p.A906Qfs*20 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | catalogued as rs1566322456, COSV61524451; called by mutect2, pindel, varscan2
- SLK | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100211496; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SNAPC4 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100046839; called by muse, mutect2, varscan2
- SNED1 | c.3103G>A p.V1035I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as rs762126032, COSV100122223; called by muse, mutect2, varscan2
- SORL1 | c.5767G>A p.V1923I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs144747223, COSV99492929; called by muse, mutect2, varscan2
- SOX10 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.782); catalogued as COSV100329658; called by muse, mutect2, varscan2
- SPATA16 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100650920; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 44/100 reads (44%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHKAP | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100763710; called by muse, mutect2, varscan2
- SPTBN1 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs557616559, COSV100441859; called by muse, mutect2, varscan2
- SPTBN1 | c.6914C>T p.A2305V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.363); catalogued as COSV100776952; called by muse, mutect2, varscan2
- SPZ1 | c.654del p.V219Sfs*23 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs537342243; called by mutect2, varscan2
- SRPRA | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99702573; called by muse, mutect2, varscan2
- SRRT | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs749488457, COSV99573762; called by muse, mutect2, varscan2
- SRSF4 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs748072495, COSV100861357, COSV65694149; called by muse, mutect2, varscan2
- SSTR5 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs565410160, COSV99559531; called by muse, mutect2, varscan2
- ST8SIA1 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99682795; called by muse, mutect2, varscan2
- ST8SIA3 | c.268T>C p.W90R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | PolyPhen possibly damaging (0.578); catalogued as COSV100129321; called by muse, mutect2
- STAB1 | c.3778T>C p.C1260R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100401251; called by muse, mutect2, varscan2
- STAT6 | c.2444dup p.G816Rfs*139 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | catalogued as rs749654830; called by mutect2, pindel, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs746501298; called by mutect2, varscan2
- STK16 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764004179, COSV99850189; called by muse, mutect2, varscan2
- STON1 | c.1433del p.K478Rfs*14 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as COSV59128672; called by mutect2, pindel, varscan2
- SULT2A1 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV55766219; called by muse, mutect2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs747003550; called by mutect2, varscan2
- SYNE1 | c.21657-1G>A p.X7219_splice (on ENST00000367255 / NM_182961.4; = p.X7148_splice on NM_033071.3) | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54955112; called by muse, mutect2, varscan2
- SYNE1 | c.15877C>G p.L5293V (on ENST00000367255 / NM_182961.4; = p.L5222V on NM_033071.3) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99554471; called by muse, mutect2
- SYVN1 | c.1235-1G>A p.X412_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53694584; called by muse, mutect2
- TBC1D14 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101298766; called by muse, mutect2, varscan2
- TBC1D19 | c.218+1G>A p.X73_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99335976; called by muse, mutect2, varscan2
- TBC1D19 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53516268, COSV99335903; called by muse, mutect2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCEA3 | c.908C>G p.T303S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101508289; called by muse, mutect2, varscan2
- TCEA3 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV101508290; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF12 | c.546del p.V183Sfs*62 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs1352708150; called by mutect2, pindel, varscan2
- TCF21 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1344260202, COSV52818773; called by muse, mutect2, varscan2
- TCF7 | c.463dup p.H155Pfs*37 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs771602751; called by mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs745872748; called by mutect2, varscan2
- TCHH | c.4961G>A p.R1654H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775186687, COSV100914909; called by muse, mutect2, varscan2
- TCHHL1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV100916501, COSV64285835; called by muse, mutect2, varscan2
- TCOF1 | c.1655C>T p.S552L (on ENST00000377797 / NM_001135243.1; = p.S475L on NM_000356.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV100076898; called by muse, mutect2
- TDRD5 | c.2018A>G p.N673S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99675538; called by muse, varscan2
- TDRD6 | c.3872T>C p.L1291P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100287155; called by muse, mutect2, varscan2
- TDRD6 | c.5809A>T p.T1937S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100287157; called by muse, mutect2, varscan2
- TEDDM1 | c.813C>A p.S271R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV100842918; called by muse, mutect2, varscan2
- TENM2 | c.5717G>A p.R1906H (on ENST00000518659 / NM_001122679.2; = p.R1667H on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs574223894, COSV69130385; called by muse, mutect2, varscan2
- TET3 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.138); catalogued as COSV99996183; called by muse, mutect2, varscan2
- TFAP2D | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1265646310, COSV99145690; called by muse, mutect2, varscan2
- TFAP2D | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs754245284, COSV50435537, COSV99145691; called by muse, mutect2, varscan2
- THEMIS2 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs200262510, COSV100197894; called by muse, mutect2, varscan2
- TLR2 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99472100; called by muse, mutect2, varscan2
- TLR6 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101126239, COSV67935770; called by muse, mutect2, varscan2
- TM6SF1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.913); catalogued as COSV99362476; called by muse, varscan2
- TMEM163 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99925710; called by muse, mutect2, varscan2
- TMEM175 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs368050248; called by muse, mutect2, varscan2
- TMEM176A | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99133551; called by muse, mutect2, varscan2
- TMEM181 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892492; called by muse, mutect2
- TMEM196 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs141997114; called by muse, mutect2, varscan2
- TMEM61 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100987727; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TMPRSS9 | c.701C>T p.A234V (on ENST00000648592; = p.A200V on NM_182973.2) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100211059; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs139852088; called by muse, mutect2, varscan2
- TP73 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs530995550, COSV60698163; called by muse, mutect2, varscan2
- TPH2 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100421863; called by muse, mutect2, varscan2
- TPR | c.5570A>C p.K1857T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100823657; called by muse, mutect2, varscan2
- TPRG1L | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs373470123; called by muse, mutect2
- TRAV30 | c.266del p.K89Sfs*? | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs373076040; called by mutect2, pindel, varscan2
- TRIM29 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs765392140, COSV59281433; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100708899; called by muse, mutect2, varscan2
- TRPM2 | c.2809T>C p.F937L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100308230; called by muse, mutect2
- TRPV5 | c.1021A>C p.I341L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99520135; called by muse, mutect2, varscan2
- TSC2 | c.2438T>C p.V813A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99552719; called by muse, mutect2, varscan2
- TSC22D1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV101488069; called by muse, mutect2
- TSPAN4 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100059445; called by muse, mutect2, varscan2
- TTC21B | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138937289; called by muse, mutect2, varscan2
- TTC26 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100570882; called by muse, mutect2, varscan2
- TTC8 | c.1216G>A p.A406T (on ENST00000338104 / NM_001288781.1; = p.A390T on NM_144596.4) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100581055; called by muse, mutect2, varscan2
- TUBA3C | c.526del p.Q176Rfs*14 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | catalogued as rs1274311012; called by mutect2, pindel, varscan2
- TUBE1 | c.746del p.K249Sfs*10 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | catalogued as rs1554315980; called by mutect2, pindel, varscan2
- TUBGCP2 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99427236; called by muse, mutect2, varscan2
- TUBGCP6 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as rs757088867, COSV99954878; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs760251146; called by mutect2, varscan2
- TYR | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs146020203; called by muse, mutect2, varscan2
- UBE2Q2 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99143194; called by muse, mutect2, varscan2
- UBIAD1 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV65147543; called by muse, mutect2, varscan2
- UGT2B17 | c.270del p.F90Lfs*2 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as rs529223604, COSV58502874; called by mutect2, pindel, varscan2
- UGT2B17 | c.55A>C p.S19R | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100497169; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs767420916; called by mutect2, varscan2
- USF1 | c.389del p.G130Vfs*33 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs1374448785; called by mutect2, pindel, varscan2
- USH1G | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV58881782; called by muse, mutect2, varscan2
- USP14 | c.997del p.Y333Ifs*7 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as rs1567836078; called by mutect2, pindel, varscan2
- USP32 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs145667783; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs764735138; called by mutect2, varscan2
- USP39 | c.851T>A p.L284H | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100083608; called by muse, mutect2, varscan2
- UTP14A | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs867109551, COSV64086681; called by muse, mutect2, varscan2
- VANGL2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1273369781, COSV100925530; called by muse, mutect2, varscan2
- VDAC1 | c.332del p.N111Mfs*34 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs772852563; called by mutect2, varscan2
- VEZF1 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99365586; called by muse, mutect2, varscan2
- VIL1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776390089, COSV99945247; called by muse, mutect2, varscan2
- VILL | c.815dup p.L273Tfs*30 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs751305489; called by mutect2, varscan2
- VILL | c.1924A>G p.I642V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1181749349, COSV99378466; called by muse, mutect2, varscan2
- VIPR2 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100056614; called by muse, mutect2, varscan2
- VPS35L | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs776063425, COSV51983889; called by muse, mutect2, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VWA3B | c.3211G>A p.G1071R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs187032973, COSV101289409, COSV101289410; called by muse, mutect2, varscan2
- WASF3 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs762162577, COSV100098158; called by muse, mutect2, varscan2
- WDFY3 | c.10507G>T p.V3503L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99882171; called by muse, mutect2, varscan2
- WDR26 | c.1025C>T p.P342L (on ENST00000414423 / NM_001379403.1; = p.P242L on NM_025160.7) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1417677519, COSV54354102; called by muse, mutect2, varscan2
- WDR70 | c.1910A>G p.E637G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV99457677; called by muse, mutect2
- WDR75 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1486562545, COSV59105932; called by muse, mutect2, varscan2
- WDR81 | c.4532G>T p.G1511V (on ENST00000409644 / NM_001163809.2; = p.G460V on NM_152348.4) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.886); catalogued as COSV100488566; called by muse, mutect2, varscan2
- WIPF1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV55812013; called by muse, mutect2, varscan2
- WIZ | c.136T>A p.S46T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.624); catalogued as COSV99652705; called by muse, mutect2
- WRNIP1 | c.1738T>C p.C580R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1374177886, COSV101062678; called by muse, mutect2, varscan2
- WSCD1 | c.907del p.R303Gfs*125 | Frame Shift Del (DEL) | VAF 53/201 reads (26%) | catalogued as rs1237564131; called by mutect2, pindel, varscan2
- XIRP2 | c.5316del p.D1773Mfs*5 (on ENST00000628543; = p.D1948Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs760810271; called by mutect2, pindel, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBBX | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100283175; called by muse, mutect2, varscan2
- ZBTB14 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs962156159, COSV63696242; called by muse, mutect2, varscan2
- ZBTB44 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.292); catalogued as COSV100777230; called by muse, mutect2, varscan2
- ZC3H12A | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1416562287, COSV100897645; called by muse, mutect2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs760469533; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC18 | c.400T>G p.F134V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100938806; called by muse, mutect2, varscan2
- ZEB2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs730881187, COSV57956280; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZFHX3 | c.4307G>A p.R1436H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1463858212, COSV51707512; called by muse, mutect2, varscan2
- ZNF211 | c.1561A>C p.S521R (on ENST00000347302 / NM_198855.4; = p.S534R on NM_006385.5) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV53743136, COSV99560038; called by muse, mutect2, varscan2
- ZNF236 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53495160; called by muse, mutect2, varscan2
- ZNF263 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV99526728; called by muse, mutect2, varscan2
- ZNF267 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1567240401, COSV100339537; called by muse, mutect2, varscan2
- ZNF274 | c.1351C>T p.R451C (on ENST00000610905; = p.R346C on NM_016324.3) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs777288675, COSV58762764; called by muse, mutect2, varscan2
- ZNF395 | c.700del p.H234Tfs*43 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs768191349; called by mutect2, varscan2
- ZNF396 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs769759761, COSV100108471; called by muse, mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF536 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100834713; called by muse, mutect2, varscan2
- ZNF550 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV100286397; called by muse, mutect2, varscan2
- ZNF584 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV100183192; called by muse, mutect2, varscan2
- ZNF646 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100336379; called by muse, mutect2, varscan2
- ZNF648 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754881990, COSV60569527; called by muse, varscan2
- ZNF776 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs750136124, COSV100414089; called by muse, mutect2, varscan2
- ZNF789 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV100507805; called by muse, mutect2, varscan2
- ZNF816 | c.190+2T>C p.X64_splice | Splice Site (SNP) | VAF 44/172 reads (26%) | catalogued as COSV99554446; called by muse, mutect2, varscan2
- ZNF846 | c.1278A>T p.E426D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV101194264; called by muse, mutect2, varscan2
- ZRANB3 | c.1597del p.R533Dfs*3 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs765112091; called by mutect2, pindel, varscan2
- AARS2 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ADAMTS6 | c.2365T>C p.Y789H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, varscan2
- AHNAK2 | c.9093dup p.S3032Lfs*132 | Frame Shift Ins (INS) | VAF 44/248 reads (18%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1942del p.V648Wfs*84 (on ENST00000458649 / NM_001367468.1; = p.V558Wfs*84 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- ANKFN1 | c.258del p.K86Nfs*22 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- ARHGAP33 | c.785del p.P262Hfs*13 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- ASH1L | c.869del p.K290Sfs*8 | Frame Shift Del (DEL) | VAF 33/188 reads (18%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, varscan2
- ATP5IF1 | c.216del p.K72Nfs*31 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- AXIN1 | c.2450del p.K817Rfs*11 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- C1RL | c.1270del p.D424Mfs*37 | Frame Shift Del (DEL) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- C9orf131 | c.3016dup p.Q1006Pfs*22 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- CAAP1 | c.575dup p.L192Ffs*5 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- CCDC146 | c.1642del p.M548Cfs*3 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- CCNG2 | c.696del p.K232Nfs*21 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- CDK16 | c.1438_1440del p.S480del | In Frame Del (DEL) | VAF 8/41 reads (20%) | called by pindel, varscan2
- CELSR2 | c.6048del p.W2017Gfs*17 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- CGNL1 | c.1753dup p.I585Nfs*16 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- CHGB | c.630dup p.E211Rfs*21 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- CHRDL1 | c.1057del p.E353Rfs*6 (on ENST00000372045; = p.E359Rfs*6 on NM_145234.4) | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- CLIC6 | c.1748del p.N583Tfs*15 (on ENST00000360731 / NM_001317009.2; = p.N565Tfs*15 on NM_053277.3) | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- COPS2 | c.777dup p.E260* | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | called by mutect2, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, varscan2
- CRAT | c.1867del p.R623Gfs*47 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- DEPTOR | c.708dup p.S237Lfs*7 | Frame Shift Ins (INS) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel, varscan2
- DLC1 | c.1472del p.L491Wfs*13 (on ENST00000276297 / NM_001348081.2; = p.L54Wfs*13 on NM_006094.5) | Frame Shift Del (DEL) | VAF 22/222 reads (10%) | called by mutect2, pindel
- DNTTIP1 | c.173_175del p.T58del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- DUS4L | c.886del p.R296Gfs*13 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.4530_4531del p.P1511Vfs*6 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by pindel, varscan2
- EBF2 | c.759dup p.C254Lfs*6 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.1240_1241del p.S414Lfs*14 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- EVI5 | c.416dup p.R140Kfs*4 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- FAM189B | c.1187del p.P396Hfs*44 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- FAS | c.403dup p.C135Lfs*2 | Frame Shift Ins (INS) | VAF 143/528 reads (27%) | called by mutect2, varscan2
- FBN3 | c.6455del p.C2152Lfs*10 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel, varscan2
- FBXO43 | c.453del p.K151Nfs*8 | Frame Shift Del (DEL) | VAF 27/166 reads (16%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1020dup p.V341Sfs*22 (on ENST00000281708 / NM_001349798.2; = p.V261Sfs*22 on NM_018315.5) | Frame Shift Ins (INS) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- FGL1 | c.450del p.K150Nfs*15 | Frame Shift Del (DEL) | VAF 11/117 reads (9%) | called by mutect2, pindel
- GEMIN5 | c.2116del p.C706Vfs*44 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- GK2 | c.1605del p.F535Lfs*2 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- HTT | c.2096del p.N699Mfs*9 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- IGHV3-66 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 28/182 reads (15%) | called by mutect2, varscan2
- IL1RAP | c.864dup p.P289Tfs*2 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, varscan2
- JAML | c.538_540del p.E180del (on ENST00000356289 / NM_001098526.2; = p.E170del on NM_153206.3) | In Frame Del (DEL) | VAF 12/67 reads (18%) | called by pindel, varscan2
- JHY | c.2216dup p.N739Kfs*13 | Frame Shift Ins (INS) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- KANK1 | c.2395del p.V799Lfs*6 | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- KAT14 | c.2046dup p.V683Sfs*11 | Frame Shift Ins (INS) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.4424del p.K1475Rfs*14 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- KIAA0895L | c.45del p.S16Afs*13 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- KIRREL1 | c.1009dup p.L337Pfs*16 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- KLHL14 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KLRG1 | c.391del p.C131Afs*5 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- KRTAP10-1 | c.534del p.C179Afs*149 | Frame Shift Del (DEL) | VAF 39/195 reads (20%) | called by mutect2, pindel, varscan2
- KYAT3 | c.347dup p.L117Afs*7 | Frame Shift Ins (INS) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- LCA5L | c.1059del p.V354Ffs*19 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- LMO7 | c.777dup p.E260* (on ENST00000357063; = p.E275* on NM_005358.5) | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- LRRC34 | c.1304del p.K435Sfs*26 (on ENST00000446859 / NM_001172779.2; = p.K403Sfs*26 on NM_153353.5) | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.1133del p.G378Vfs*47 (on ENST00000528054; = p.G347Vfs*47 on NM_019839.5) | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.678dup p.E227* | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- MAST2 | c.2178del p.F726Lfs*12 | Frame Shift Del (DEL) | VAF 53/186 reads (28%) | called by mutect2, pindel, varscan2
- MECOM | c.666_667del p.C222Wfs*12 (on ENST00000468789 / NM_001105078.4; = p.C410Wfs*12 on NM_004991.4) | Frame Shift Del (DEL) | VAF 26/131 reads (20%) | called by pindel, varscan2
- MUTYH | c.587del p.G196Afs*41 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, varscan2
- NAA16 | c.186del p.E63Kfs*38 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by pindel, varscan2
- NCOA3 | c.3181_3183del p.L1061del | In Frame Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- NOS3 | c.2526del p.G843Afs*115 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.3461del p.G1154Afs*150 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- NR5A2 | c.330del p.F110Lfs*14 (on ENST00000367362 / NM_205860.3; = p.F64Lfs*14 on NM_003822.5) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- NYNRIN | c.344del p.P115Lfs*4 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel
- OR13C5 | c.39del p.L14* | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- OR4K14 | c.273dup p.L92Tfs*21 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel
- ORC2 | c.145del p.I49* | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- OSBP2 | c.1887del p.S630Qfs*34 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.2377_2378del p.N793* (on ENST00000319481 / NM_080597.4; = p.N280* on NM_018030.4) | Frame Shift Del (DEL) | VAF 32/182 reads (18%) | called by mutect2, pindel, varscan2
- PAK2 | c.1466del p.G489Vfs*12 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- PEX16 | c.630del p.T211Pfs*44 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- PHRF1 | c.2813dup p.E939Rfs*5 (on ENST00000264555 / NM_001286581.2; = p.E938Rfs*5 on NM_020901.4) | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- PLXNA4 | c.3689del p.P1230Rfs*42 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- POLB | c.504del p.V169Wfs*27 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- POSTN | c.542del p.N181Mfs*3 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- PRDM2 | c.4277del p.N1426Ifs*3 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, varscan2
- PRKAR2B | c.624dup p.G209Wfs*6 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.3563del p.N1188Mfs*7 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1203del p.G402Efs*21 | Frame Shift Del (DEL) | VAF 42/170 reads (25%) | called by mutect2, pindel, varscan2
- RCBTB2 | c.298del p.I100* | Frame Shift Del (DEL) | VAF 32/164 reads (20%) | called by mutect2, pindel, varscan2
- RHBDF2 | c.882del p.F294Lfs*6 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | called by mutect2, pindel, varscan2
- RIT1 | c.588del p.K196Nfs*12 | Frame Shift Del (DEL) | VAF 57/272 reads (21%) | called by mutect2, pindel, varscan2
- SASH3 | c.133_135del p.E45del | In Frame Del (DEL) | VAF 22/35 reads (63%) | called by mutect2, pindel, varscan2
- SEC63 | c.1587_1596delinsAGAAACCTTT p.K530_L532delinsETF | Missense Mutation (ONP) | VAF 11/119 reads (9%) | called by pindel, varscan2*
- SGPP1 | c.1290dup p.V431Cfs*19 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- SOAT1 | c.1487del p.K496Sfs*7 | Frame Shift Del (DEL) | VAF 48/181 reads (27%) | called by mutect2, pindel, varscan2
- SORBS2 | c.1692del p.A565Lfs*49 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- SPARCL1 | c.20del p.F7Sfs*29 | Frame Shift Del (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel, varscan2
- SPEM1 | c.676del p.A226Rfs*35 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, varscan2
- SUGP2 | c.763del p.I255Yfs*4 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | called by mutect2, varscan2
- SYCP2 | c.3953_3954del p.C1318* | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by pindel, varscan2
- SYN3 | c.1219del p.L407Sfs*23 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- TASOR | c.4308dup p.E1437Rfs*4 (on ENST00000355628 / NM_001365636.2; = p.E1061Rfs*4 on NM_015224.3) | Frame Shift Ins (INS) | VAF 28/75 reads (37%) | called by mutect2, pindel, varscan2
259 further variants in this file (21 protein-altering or splice-affecting, 220 silent, 18 other) are not listed here.
